Somatic mutation profile of tumor specimen MBCProject_0988_T1_WES (aliquot MBCProject_0988_T1_WES_1) from CMI case MBCProject_0988, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 36.4 years (13,283 days).
Specimen MBCProject_0988_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d57d550a-e036-4b12-829a-239ea5d8da5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0988_SALIVA (Saliva), aliquot MBCProject_0988_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93db2e24-85af-4126-8762-c8f13d0e36a2

The open-access MAF lists 32 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, RNA 3, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH12 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 68/329 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs147080212; called by muse, mutect2, varscan2
- GATA3 | c.1312_1313dup p.M438Ifs*38 | Frame Shift Ins (INS) | VAF 28/117 reads (24%) | catalogued as COSV60516892; called by mutect2, pindel, varscan2
- HERC2 | c.3308T>C p.I1103T | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs372777009; called by muse, mutect2, varscan2
- KRTAP19-1 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 117/412 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs371788350, COSV66861122; called by muse, mutect2, varscan2
- SMARCA4 | c.2392G>T p.E798* | Nonsense Mutation (SNP) | VAF 49/207 reads (24%) | catalogued as COSV60785922; called by muse, mutect2, varscan2
- SSTR1 | c.272C>G p.T91R | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753890091; called by muse, mutect2, varscan2
- TEX15 | c.238G>A p.D80N (on ENST00000256246; = p.D463N on NM_001350162.2) | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as rs1180970099; called by muse, mutect2, varscan2
- ZBTB11 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 23/98 reads (23%) | catalogued as rs1222509693, COSV100465000; called by muse, mutect2, varscan2
- ADAMTS5 | c.1214C>A p.A405D | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP4 | c.826T>C p.Y276H | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- CAPNS2 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC168 | c.11966G>T p.G3989V | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- COL4A1 | c.1400G>T p.C467F | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL6A5 | c.7138C>A p.L2380I (on ENST00000312481; = p.L2376I on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DCAF4 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2
- ELAVL1 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ETFA | c.665-5A>G | Splice Region (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- IFNG | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- MPP6 | c.1255A>C p.I419L | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SMARCA4 | c.2391G>T p.M797I | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ABCB7 | c.1950C>T p.A650= (on ENST00000373394 / NM_001271696.3; = p.A651= on NM_004299.6) | Silent (SNP) | VAF 42/168 reads (25%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.132C>T p.S44= | Silent (SNP) | VAF 44/138 reads (32%) | called by muse, mutect2, varscan2
- BRIX1 | c.405C>T p.H135= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs368231240; called by muse, mutect2, varscan2
- DNHD1 | c.3492G>A p.A1164= | Silent (SNP) | VAF 81/298 reads (27%) | catalogued as rs1039587516; called by muse, mutect2, varscan2
- NALCN | c.2886T>C p.Y962= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1318122754; called by muse, varscan2
- TSPAN8 | c.670T>C p.L224= | Silent (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- XRRA1 | c.1809G>C p.R603= | Silent (SNP) | VAF 113/332 reads (34%) | catalogued as rs766432171; called by muse, varscan2
- CACNA1G | c.*335C>T | 3'UTR (SNP) | VAF 111/341 reads (33%) | catalogued as rs1046572336; called by muse, mutect2, varscan2
- COL6A4P1 | n.385C>T | RNA (SNP) | VAF 67/252 reads (27%) | catalogued as rs758170407; called by muse, mutect2, varscan2
- DCHS2 | n.7970G>T | RNA (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- SDHAP1 | n.1256G>T | RNA (SNP) | VAF 14/259 reads (5%) | called by muse, mutect2
- TSN | c.160+118G>T | Intron (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
